CCDI case PBBYIK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/590b5b81-2d99-49f4-99a9-a594b659d7ba

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; Tissue or organ of origin: Tail of pancreas; Age at diagnosis: 10.9 years (3,967 days).

Biospecimens (3 samples)
- Sample 0DKGXA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKGXD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKGYU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
